Gene-level copy-number profile of tumor specimen TCGA-ZM-AA05-01A from TCGA case TCGA-ZM-AA05, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 36.4 years (13,295 days).
Specimen TCGA-ZM-AA05-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.41e81e90-8e68-4fa5-988e-4a617c521aea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZM-AA05-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a5c6dac-0b1d-4868-90c2-e4092974f828

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 4,213; copy number 2: 23,022; copy number 3: 23,378; copy number 4: 8,666; copy number 5: 479.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZM-AA05-01A-12D-A434-01): tumor purity 0.33, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:121,361,854–123,841,930, 54 genes (within-gene range 0–1): BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1, AP001924.1, RNU6-256P, AP001924.2, MIR100HG, MIR125B1, BLID, MIRLET7A2, MIR100, AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1, UBASH3B, AP002762.3, AP002762.1, AP002762.2, CRTAM, JHY, RNU4-23P, ATP5PBP5, BSX, AP003040.1, RPL34P23, RPS26P43, RPL31P47, HSPA8, SNORD14E, SNORD14D, SNORD14C, AP000926.2, CLMP, AP000926.1, AP001970.1, U8, LINC02727, PHBP17, GRAMD1B, MIR4493, SF3A3P2, SCN3B, AP002765.1, ZNF202, OR6X1, RNU1-21P, OR6M1, OR6M2P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
